Somatic mutation profile of tumor specimen 0DPQRT from CCDI case PBCEEN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,547 days).
Specimen 0DPQRT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5045f3cd-0479-45c4-88b6-0903e36d55cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPQRR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04c9cb2f-a41d-4be0-a7b4-4ff471b9c2f5

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/636 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FFAR2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs568119991, COSV55833001; called by muse, mutect2, varscan2
- SLC25A13 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 84/1008 reads (8%) | called by muse, mutect2
- CBLN4 | c.360C>T p.Y120= | Silent (SNP) | VAF 63/499 reads (13%) | called by muse, mutect2, varscan2
- KAZN | c.354C>T p.T118= | Silent (SNP) | VAF 52/353 reads (15%) | catalogued as rs200260939, COSV100747765, COSV100748001; called by muse, mutect2, varscan2
- NHLH2 | c.180G>A p.P60= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as rs1238348168; called by muse, mutect2, varscan2
- ERBB4 | c.2487+56C>T | Intron (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2
